CCDI case PBCAFN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6ca0c84b-5fa3-4c92-814d-6bb2d84025fb

Demographics
Sex at birth: male.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.1 years (2,962 days).

Biospecimens (3 samples)
- Sample 0DMBLH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMBM1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMBM7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
